MMRF case MMRF_2722 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/aaa84c57-e5f1-4983-ba99-07da80838185

Demographics
Sex at birth: male; Age at index: 60 years; Vital status: Dead; Days to death: 169 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; ISS stage: II; Days to last known disease status: 169 days; Days to last follow up: 169 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -4, day 169.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Albumin 29.4 g/L.
- Lactate Dehydrogenase 21.3 µkat/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL.
- Beta 2 Microglobulin 3.8 µg/mL.
- M Protein 3.6 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL.
- Creatinine 65.4 µmol/L.
- Absolute Neutrophil 10.1 ×10⁹/L.
- Platelets 152 ×10⁹/L.
- Hemoglobin 6.51 mmol/L.

Other clinical attributes
- Day -4: Weight: 112 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2722_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2722_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
